Somatic mutation profile of tumor specimen TARGET-20-PARDZW-09A (aliquot TARGET-20-PARDZW-09A-01D) from TARGET case TARGET-20-PARDZW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,808 days).
Specimen TARGET-20-PARDZW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c7b2573-9d5f-4541-82d5-ab62d6051207.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARDZW-14A (Bone Marrow Normal), aliquot TARGET-20-PARDZW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c2b9fbf-25bc-4cb9-b9f4-61cd6335620e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 33/82 reads (40%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- SMC3 | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62419573, COSV62420076; called by muse, mutect2, varscan2
- TET2 | c.3640C>T p.R1214W | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761811530, COSV54395395; called by muse, mutect2, varscan2
